CPTAC case C3L-05315 — Hematopoietic and reticuloendothelial systems — Myeloid Leukemias (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Myeloid Leukemias; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/28e559bc-16f6-42f5-b2ee-7d6e78fed5b2

Demographics
Sex at birth: male; Race: white; Year of birth: 1967; Vital status: Alive; Country of birth: Serbia.

Diagnoses (1)
1. Acute myeloid leukemia, NOS: ICD-O-3 morphology code: 9861/3; Tissue or organ of origin: Hematopoietic system, NOS; Site of resection or biopsy: Hematopoietic system, NOS; Age at diagnosis: 52.2 years (19,073 days); Year of diagnosis: 2019; Days to last known disease status: 13 days; Days to last follow up: 13 days.

Follow-up (1 entry)
- Days to follow up: 13 days; Karnofsky performance status: 90; ECOG performance status: 1.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker for > 15 yrs; Pack years smoked: 42; Cigarettes per day: 40; Tobacco smoking onset year: 1981; Tobacco smoking quit year: 2002; Alcohol history: Yes; Alcohol intensity: Not Heavy Drinker; Exposure duration years: 21.

Biospecimens (5 samples)
- Samples C3L-05315-50, C3L-05315-51, C3L-05315-52 (3 with the same recorded description): Sample type: Buccal Cell Normal; Tissue type: Normal; Specimen type: Buccal Cells; Preservation method: Frozen; Freezing method: -80 (unit not recorded by GDC).
- Samples C3L-05315-54, C3L-05315-55 (2 with the same recorded description): Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -80 (unit not recorded by GDC); Days to sample procurement: 6 days; Method of sample procurement: Blood Draw; Diagnosis pathologically confirmed: Yes.
